Somatic mutation profile of tumor specimen TCGA-DU-6394-01A (aliquot TCGA-DU-6394-01A-11D-1705-08) from TCGA case TCGA-DU-6394, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 53.5 years (19,541 days).
Specimen TCGA-DU-6394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63107403-4a39-46ca-b2ca-ffaec97345a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6394-10A (Blood Derived Normal), aliquot TCGA-DU-6394-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbb3b501-3ce1-4a2b-ad6b-aa027f17c8bc

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, In Frame Del 7, Frame Shift Del 5, Silent 5, Splice Site 3, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGD | c.970del p.V324Lfs*16 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | catalogued as rs34214309; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.1541_1542del p.Q514Rfs*43 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs267606600, COSV62194613; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1698_1700del p.K567del (on ENST00000521381 / NM_181523.3; = p.K297del on NM_181504.4) | In Frame Del (DEL) | VAF 14/112 reads (13%) | hotspot (GDC flag); catalogued as COSV57129081; called by mutect2, pindel, varscan2
- BCORL1 | c.513_515del p.K171del | In Frame Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs774058034; called by pindel, varscan2
- CEP104 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764366578, COSV58215086; called by mutect2, varscan2
- ENKD1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1241559567, COSV54676681; called by muse, mutect2, varscan2
- FRMPD4 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66218223; called by muse, mutect2, varscan2
- IRF2BP1 | c.1655G>T p.C552F | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56194159; called by muse, mutect2, varscan2
- KRTAP13-1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs374257240, COSV62664445; called by muse, mutect2, varscan2
- NF1 | c.7189+2T>A p.X2397_splice (on ENST00000358273 / NM_001042492.3; = p.X2376_splice on NM_000267.3) | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as CS1512944, COSV62209232, COSV62227280; called by muse, mutect2, varscan2
- NPAS3 | c.1301+2T>G p.X434_splice (on ENST00000356141 / NM_001164749.2; = p.X402_splice on NM_022123.3) | Splice Site (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100640804, COSV60843804; called by muse, mutect2, varscan2
- NPTX1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1405442502, COSV60775568; called by muse, mutect2, varscan2
- NT5C | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV55461207; called by muse, mutect2, varscan2
- PGLYRP2 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1198286152, COSV52995516, COSV52996882; called by muse, mutect2
- PHACTR3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 70/345 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763187430, COSV63030491; called by muse, mutect2, varscan2
- PLIN4 | c.3014_3016del p.T1005del (on ENST00000301286; = p.T1020del on NM_001367868.2) | In Frame Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs1447334279; called by pindel, varscan2
- PWP2 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52386596; called by mutect2, varscan2
- SMC4 | c.1825T>A p.S609T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1442392775, COSV61006064; called by muse, mutect2, varscan2
- THEMIS | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as rs868167768, COSV64069556, COSV64070385; called by muse, mutect2, varscan2
- ZDHHC11 | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); catalogued as COSV52071105, COSV52071468; called by muse, mutect2, varscan2
- FAM149A | c.1807_1809del p.S603del (on ENST00000356371 / NM_001367768.2; = p.S312del on NM_015398.3 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- FUBP1 | c.248_250+1del p.X83_splice | Splice Site (DEL) | VAF 20/30 reads (67%) | called by mutect2, pindel, varscan2
- HDAC2 | c.297_299del p.E99del | In Frame Del (DEL) | VAF 14/31 reads (45%) | called by pindel, varscan2
- MAN2A1 | c.349_352del p.F118Lfs*19 | Frame Shift Del (DEL) | VAF 34/151 reads (23%) | called by pindel, varscan2
- NOTCH1 | c.6193_6194del p.L2065Vfs*202 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.2105_2107del p.N702del | In Frame Del (DEL) | VAF 17/138 reads (12%) | called by pindel, varscan2
- WASL | c.93_97del p.T32Pfs*36 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- WDFY3 | c.2054_2056del p.L685del | In Frame Del (DEL) | VAF 27/70 reads (39%) | called by pindel, varscan2
- FKBP8 | c.504G>A p.T168= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as rs376393547; called by muse, mutect2, varscan2
- JAG2 | c.1641C>T p.N547= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as rs766540205, COSV59306111, COSV59309896; called by muse, mutect2, varscan2
- NOS1 | c.3282C>T p.T1094= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs769020729, COSV57615790; called by muse, mutect2, varscan2
- NPY1R | c.588C>T p.Y196= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs189884361, COSV56715239; called by muse, mutect2, varscan2
- TXK | c.300T>C p.N100= | Silent (SNP) | VAF 27/173 reads (16%) | catalogued as rs369849027; called by muse, mutect2, varscan2
- DNAH8 | chr6:38722823 C>T | 5'Flank (SNP) | VAF 11/25 reads (44%) | catalogued as COSV59460483; called by muse, mutect2, varscan2
